Somatic mutation profile of tumor specimen TCGA-CD-8531-01A (aliquot TCGA-CD-8531-01A-11D-2340-08) from TCGA case TCGA-CD-8531, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 66.9 years (24,453 days).
Specimen TCGA-CD-8531-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b13cfe2-a18c-4533-8a3b-bf392894126b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CD-8531-10A (Blood Derived Normal), aliquot TCGA-CD-8531-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30bac9a3-b2ef-4062-9826-0e99e4c57bad

The open-access MAF lists 261 somatic variants for this specimen: 195 protein-altering or splice-affecting, 61 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 164, Silent 61, Nonsense Mutation 13, Frame Shift Del 11, Intron 4, Splice Site 3, Splice Region 2, Frame Shift Ins 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AR | c.2324G>A p.R775H | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs137852572, CM136027, CM920086, COSV65954067; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FAS | c.*18_*19insT | 3'UTR (INS) | VAF 30/91 reads (33%) | catalogued as rs606231366, COSV58239495; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.71A>T p.D24V | Missense Mutation (SNP) | VAF 30/87 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as CM110138, CM141438, COSV64293188, COSV64296384, COSV64307484; called by muse, varscan2
- TP53 | c.725G>A p.C242Y | Missense Mutation (SNP) | VAF 17/37 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912655, CM910618, COSV52661189, COSV52677418, COSV52689710; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACHE | c.375G>T p.E125D | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53818775; called by muse, mutect2, varscan2
- ADGRL3 | c.1957G>T p.A653S (on ENST00000506720 / NM_001322402.2; = p.A585S on NM_015236.6) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.792); catalogued as rs754482324, COSV63368410, COSV63368438; called by muse, mutect2, varscan2
- AKR1C1 | c.145A>G p.I49V | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV66499364; called by muse, mutect2, varscan2
- AL592490.1 | c.2317G>A p.D773N | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69426784; called by muse, mutect2, varscan2
- ALDH1B1 | c.1396G>A p.G466R | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as rs750694017, COSV100890901, COSV66620133; called by muse, mutect2, varscan2
- ALK | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.078); catalogued as rs1337143722, COSV66574657; called by muse, mutect2, varscan2
- ANKRD11 | c.7736G>A p.R2579H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1250432793, COSV56355400; called by muse, mutect2, varscan2
- ANKRD50 | c.2263G>T p.A755S | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.958); catalogued as COSV72385832; called by muse, mutect2, varscan2
- ATP5F1B | c.748A>T p.M250L | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.174); catalogued as COSV56261399; called by muse, mutect2, varscan2
- ATRX | c.2729A>C p.K910T | Missense Mutation (SNP) | VAF 119/429 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.696); catalogued as COSV64878855; called by muse, mutect2, varscan2
- BAIAP2L1 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368033137; called by muse, mutect2, varscan2
- BBOX1 | c.496G>T p.G166W | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54191977, COSV99589911; called by muse, mutect2, varscan2
- BBS9 | c.366G>C p.Q122H | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.976); catalogued as COSV54174369; called by muse, mutect2, varscan2
- BCL11A | c.1258G>A p.D420N (on ENST00000335712 / NM_001365609.1; = p.D454N on NM_018014.4) | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs754152321, COSV59632950; called by muse, mutect2, varscan2
- BCL11B | c.2099C>T p.A700V (on ENST00000357195 / NM_001282237.2; = p.A629V on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.457); catalogued as rs115625258; called by muse, mutect2, varscan2
- BRWD3 | c.2932A>T p.M978L | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV64750077; called by mutect2, varscan2
- CATSPERE | c.370T>C p.Y124H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63679276; called by muse, mutect2, varscan2
- CCDC115 | c.112G>T p.G38C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52092118; called by muse, mutect2, varscan2
- CCR6 | c.1005G>A p.W335* | Nonsense Mutation (SNP) | VAF 24/63 reads (38%) | catalogued as COSV59475467; called by muse, mutect2, varscan2
- CD209 | c.870G>C p.Q290H | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52655312; called by muse, mutect2, varscan2
- CDH18 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.958); catalogued as rs750768779, COSV56917098; called by muse, mutect2, varscan2
- CEACAM5 | c.1270T>C p.Y424H | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.808); catalogued as COSV55753044; called by muse, mutect2, varscan2
- CNTN4 | c.2974A>G p.I992V | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV61875480; called by muse, mutect2, varscan2
- CNTNAP2 | c.734T>C p.L245P | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62207512; called by muse, mutect2, varscan2
- CORO1A | c.1113C>A p.D371E | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54631520; called by muse, mutect2, varscan2
- CXorf66 | c.451A>T p.S151C | Missense Mutation (SNP) | VAF 318/487 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV65169200; called by muse, varscan2
- DAB1 | c.796T>C p.F266L | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100976202; called by muse, mutect2, varscan2
- DENND2B | c.2471C>T p.A824V | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as COSV58205157; called by muse, mutect2, varscan2
- DENND6B | c.824T>A p.L275Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV69807144; called by muse, mutect2, varscan2
- DOCK4 | c.3279G>T p.M1093I | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.417); catalogued as COSV69854869; called by muse, mutect2, varscan2
- DOT1L | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67110810; called by muse, mutect2, varscan2
- DRC1 | c.2120A>T p.Q707L | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV55507581; called by muse, mutect2, varscan2
- DTX1 | c.173G>C p.G58A | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57496121, COSV57498714; called by muse, varscan2
- DTX1 | c.244T>C p.F82L | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV57498725; called by muse, varscan2
- EEF1A1 | c.1250A>G p.D417G | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.099); catalogued as COSV58550063; called by muse, mutect2, varscan2
- ERVW-1 | c.176C>T p.T59I | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.035); catalogued as COSV101423817; called by muse, mutect2, varscan2
- F9 | c.782G>T p.W261L | Missense Mutation (SNP) | VAF 81/204 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as CM940578, COSV54381071; called by muse, mutect2, varscan2
- FAM155A | c.92A>G p.D31G | Missense Mutation (SNP) | VAF 57/181 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV65569200; called by muse, mutect2, varscan2
- FAM47C | c.2273G>A p.R758H | Missense Mutation (SNP) | VAF 93/159 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.151); catalogued as rs376888720, COSV63726995; called by muse, mutect2, varscan2
- FAT2 | c.12686C>T p.P4229L | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55822919; called by muse, mutect2, varscan2
- FAT3 | c.754C>A p.L252I | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV53132094; called by muse, mutect2, varscan2
- FAT3 | c.3184G>A p.V1062M | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs774197887, COSV53100354; called by muse, mutect2, varscan2
- FAT4 | c.4097G>A p.S1366N | Missense Mutation (SNP) | VAF 72/160 reads (45%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.974); catalogued as COSV67890738, COSV67896057; called by muse, mutect2, varscan2
- FAT4 | c.8364del p.L2789* | Frame Shift Del (DEL) | VAF 45/133 reads (34%) | catalogued as COSV58674572; called by mutect2, varscan2
- FGD6 | c.16+2T>A p.X6_splice | Splice Site (SNP) | VAF 9/19 reads (47%) | catalogued as COSV99703587; called by muse, mutect2, varscan2
- FKBP1A | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs760096309, COSV67750588, COSV67750705; called by muse, mutect2, varscan2
- FRAS1 | c.8467C>T p.R2823C | Missense Mutation (SNP) | VAF 78/220 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs372605917; called by muse, mutect2, varscan2
- FRMPD1 | c.3966T>G p.N1322K | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.94); PolyPhen benign (0.007); catalogued as COSV66700946; called by muse, mutect2, varscan2
- GBF1 | c.4969C>T p.H1657Y (on ENST00000369983 / NM_001377137.1; = p.H1656Y on NM_004193.3) | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as COSV64146320; called by muse, mutect2, varscan2
- GBP6 | c.1298A>C p.K433T | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as COSV65011884; called by muse, mutect2, varscan2
- GPR139 | c.956T>A p.F319Y | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.827); catalogued as COSV104399099, COSV58502421, COSV58503584; called by muse, mutect2, varscan2
- GPR39 | c.365C>T p.T122M | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375756316; called by muse, mutect2, varscan2
- GRB2 | c.19T>G p.Y7D | Missense Mutation (SNP) | VAF 113/133 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV57305356; called by muse, mutect2, varscan2
- GRIP1 | c.2038G>A p.G680R (on ENST00000359742 / NM_001379345.1; = p.G628R on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs750092161, COSV54029492, COSV54033744; called by muse, mutect2, varscan2
- GRN | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 39/43 reads (91%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as COSV50007666; called by muse, mutect2, varscan2
- GTDC1 | c.778G>A p.G260S | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.025); catalogued as COSV53987459, COSV53998471; called by muse, mutect2, varscan2
- H1-2 | c.434C>G p.A145G | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs141266449; called by muse, varscan2
- H1-2 | c.407A>T p.K136M | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59191242; called by muse, varscan2
- H2AC14 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.059); catalogued as rs775610633, COSV60798137; called by muse, mutect2, varscan2
- H2BC12 | c.80G>A p.G27D | Missense Mutation (SNP) | VAF 59/205 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1252757567, COSV63616630; called by muse, mutect2, varscan2
- HFM1 | c.1988C>G p.T663R | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV54030585, COSV54031672; called by muse, mutect2, varscan2
- HK3 | c.1499T>G p.V500G | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52841709; called by muse, mutect2, varscan2
- HLA-B | c.149G>A p.G50D | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs281864589, COSV69520839; called by muse, mutect2, varscan2
- IFT122 | c.2969C>T p.P990L (on ENST00000348417 / NM_052989.3; = p.P931L on NM_018262.4) | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV56204680; called by muse, mutect2
- IGHJ6 | c.32G>C p.G11A | Missense Mutation (SNP) | VAF 5/27 reads (19%) | PolyPhen possibly damaging (0.665); catalogued as rs368585758; called by muse, varscan2
- IGHV4-34 | c.183C>G p.S61R | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as rs11546809; called by muse, varscan2
- IGHV4-34 | c.182G>A p.S61N | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs11546815; called by muse, varscan2
- IGKJ1 | c.17A>G p.Q6R | Missense Mutation (SNP) | VAF 22/29 reads (76%) | catalogued as rs760672671; called by muse, varscan2
- IGKV1-5 | c.116A>G p.D39G | Missense Mutation (SNP) | VAF 49/64 reads (77%) | SIFT tolerated (0.1); PolyPhen benign (0.246); catalogued as rs558608711; called by muse, mutect2, varscan2
- IGKV4-1 | c.185A>G p.Y62C | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as rs140954172; called by muse, mutect2, varscan2
- IHH | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.684); catalogued as rs200898513, COSV55393501; called by muse, mutect2, varscan2
- KBTBD3 | c.523C>G p.H175D | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV73241498; called by muse, mutect2, varscan2
- KEL | c.1021G>C p.E341Q | Missense Mutation (SNP) | VAF 86/236 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV62335912; called by muse, mutect2, varscan2
- KLC4 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV52436921; called by muse, mutect2, varscan2
- KLF12 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV66575220; called by muse, mutect2, varscan2
- LAMA5 | c.1166G>A p.G389D | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53355555; called by muse, mutect2, varscan2
- LCE1B | c.290G>A p.S97N | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.325); catalogued as COSV63980414; called by muse, varscan2
- LGR4 | c.255G>C p.E85D | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV64864913; called by muse, mutect2, varscan2
- LHFPL5 | c.73G>C p.V25L | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV100798931, COSV64178172; called by muse, mutect2, varscan2
- LMOD2 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766289909, COSV71755692; called by muse, mutect2, varscan2
- LYN | c.1229C>T p.T410M | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1347486935, COSV70205591; called by muse, mutect2, varscan2
- MAD1L1 | c.1982A>G p.D661G | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56238765; called by muse, mutect2, varscan2
- MADD | c.1306A>T p.S436C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60625845; called by muse, mutect2, varscan2
- MAGEB4 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs866215650, COSV66775758, COSV66775982; called by muse, mutect2
- MAGEC3 | c.1369G>T p.D457Y | Missense Mutation (SNP) | VAF 88/123 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.281); catalogued as COSV68923863; called by muse, mutect2, varscan2
- MAP3K20 | c.289A>T p.N97Y | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as rs746903757, COSV59104406; called by muse, mutect2, varscan2
- MAPKBP1 | c.2192G>A p.R731H (on ENST00000456763 / NM_001128608.2; = p.R725H on NM_014994.3) | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776066473, COSV52963623; called by muse, mutect2, varscan2
- MGA | c.2652T>G p.Y884* | Nonsense Mutation (SNP) | VAF 44/109 reads (40%) | catalogued as COSV54957042; called by muse, mutect2, varscan2
- MICAL2 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs766049584, COSV56322016; called by muse, mutect2, varscan2
- MICAL2 | c.1420C>G p.L474V | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV56322029; called by muse, mutect2, varscan2
- MKLN1 | c.1892T>G p.L631* | Nonsense Mutation (SNP) | VAF 34/82 reads (41%) | catalogued as COSV61761567; called by muse, mutect2, varscan2
- MROH5 | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV71302064; called by muse, mutect2, varscan2
- MT1M | c.85T>A p.C29S | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV65835815; called by muse, mutect2
- MYO1F | c.1129C>G p.Q377E | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.81); PolyPhen benign (0.009); catalogued as COSV57796727; called by muse, mutect2, varscan2
- NECAB1 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as COSV70241224; called by muse, mutect2, varscan2
- NELFCD | c.1781A>C p.N594T (on ENST00000602795; = p.N576T on NM_198976.4) | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); catalogued as COSV53883929; called by muse, mutect2, varscan2
- NELFE | c.430C>G p.R144G | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.4); catalogued as COSV64811058, COSV64812477; called by muse, mutect2, varscan2
- NFATC4 | c.2014C>T p.R672W | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs748592990, COSV51605420; called by muse, mutect2, varscan2
- NFKB1 | c.1345A>C p.S449R (on ENST00000394820 / NM_001382627.1; = p.S450R on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.042); catalogued as COSV56957970; called by muse, mutect2, varscan2
- NLRP2 | c.1210G>A p.V404M | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs763533364, COSV54756745; called by muse, mutect2, varscan2
- NOTCH3 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54634094; called by muse, mutect2
- NRBP1 | c.341T>G p.V114G | Missense Mutation (SNP) | VAF 99/255 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV51994801; called by muse, mutect2, varscan2
- NRG1 | c.1292C>T p.P431L (on ENST00000405005 / NM_013964.5; = p.P436L on NM_013956.5) | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753126752, COSV55164808; called by muse, mutect2, varscan2
- OBSCN | c.4244C>T p.A1415V | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.821); catalogued as rs368916370; called by muse, mutect2, varscan2
- OGDHL | c.1906C>T p.R636W | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs773683494, COSV65102684, COSV65103288; called by muse, mutect2, varscan2
- OR10G9 | c.336C>A p.F112L | Missense Mutation (SNP) | VAF 41/260 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as COSV100901513; called by muse, mutect2, varscan2
- OR13C9 | c.33A>T p.E11D | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs144981085, COSV52242591; called by muse, mutect2, varscan2
- OR2J2 | c.815G>A p.G272D | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as rs750646669, COSV65847858, COSV65848137; called by muse, mutect2, varscan2
- PAK5 | c.2110G>C p.G704R | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as COSV62029013, COSV62030762; called by muse, mutect2
- PCDH10 | c.1100T>C p.V367A | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52097361; called by muse, mutect2, varscan2
- PCDH15 | c.4543T>G p.Y1515D (on ENST00000644397 / NM_001354429.2; = p.I1475M on NM_001142770.3) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV64705793; called by muse, mutect2, varscan2
- PCDHA11 | c.2297C>T p.T766M | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.046); catalogued as rs146613275, COSV56510755; called by muse, mutect2, varscan2
- PDS5A | c.1388T>A p.L463Q | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57827552; called by muse, mutect2, varscan2
- PHOX2B | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs1442934701, COSV56930288; called by muse, mutect2, varscan2
- PLCB2 | c.1236C>T p.D412= | Splice Region (SNP) | VAF 10/28 reads (36%) | catalogued as rs750364378, COSV53035075; called by muse, mutect2, varscan2
- POU4F2 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs546678292, COSV55585317, COSV99029068; called by muse, mutect2, varscan2
- PPP1R9A | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV56898562; called by muse, mutect2, varscan2
- PRDM1 | c.1814G>A p.C605Y | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64845531; called by muse, mutect2
- PRSS35 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63800785; called by muse, mutect2, varscan2
- PTEN | c.16A>G p.K6E | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as CM142085, COSV64291830; called by muse, varscan2
- PTPRB | c.3182A>T p.Y1061F | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54244812; called by muse, mutect2, varscan2
- PTPRM | c.552G>T p.R184S | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV59866943; called by muse, mutect2, varscan2
- PTPRZ1 | c.4517C>T p.P1506L | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.003); catalogued as rs1427661666, COSV66440150; called by muse, mutect2, varscan2
- PTPRZ1 | c.6581C>T p.P2194L | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66440157; called by muse, mutect2, varscan2
- RALB | c.154A>G p.R52G | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55603801; called by muse, mutect2, varscan2
- RBM43 | c.823C>T p.H275Y | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV58879013; called by muse, mutect2, varscan2
- RIMBP2 | c.1471C>T p.Q491* | Nonsense Mutation (SNP) | VAF 5/10 reads (50%) | catalogued as COSV55476584; called by muse, mutect2, varscan2
- RIT2 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757214621, COSV58659703; called by muse, mutect2, varscan2
- RLBP1 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200725857, CM051981; called by muse, mutect2, varscan2
- RSPO2 | c.215G>C p.G72A | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52647834, COSV99410592; called by muse, mutect2, varscan2
- SCN1B | c.420G>C p.K140N | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52894561; called by muse, mutect2, varscan2
- SENP1 | c.1614T>C p.V538= | Splice Region (SNP) | VAF 7/17 reads (41%) | catalogued as COSV50294282; called by muse, mutect2, varscan2
- SGIP1 | c.806T>C p.I269T | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs760769944, COSV52772406; called by muse, mutect2, varscan2
- SIAH2 | c.211C>G p.H71D | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100469167; called by muse, mutect2
- SLC13A2 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781999580, COSV58992636; called by muse, mutect2, varscan2
- SLC16A3 | c.224G>A p.G75D | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66429251; called by muse, mutect2, varscan2
- SLC22A8 | c.1054G>A p.G352R | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60323406; called by muse, mutect2, varscan2
- SLITRK5 | c.1793T>A p.F598Y | Missense Mutation (SNP) | VAF 60/152 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.299); catalogued as COSV61523760; called by muse, mutect2, varscan2
- SPEN | c.2014C>T p.R672* | Nonsense Mutation (SNP) | VAF 56/107 reads (52%) | catalogued as COSV65363795; called by muse, mutect2, varscan2
- SPRYD7 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1298475535, COSV62524381; called by muse, mutect2, varscan2
- SV2A | c.660C>A p.F220L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.123); catalogued as COSV64964789, COSV64965190; called by muse, mutect2, varscan2
- SYNGAP1 | c.3376G>A p.G1126S | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.171); catalogued as COSV53382908; called by muse, mutect2
- SYT10 | c.1127C>T p.T376M | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1305410203, COSV57337687; called by muse, mutect2, varscan2
- TBX5 | c.591A>C p.K197N | Missense Mutation (SNP) | VAF 60/245 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV59862572, COSV59863463; called by muse, mutect2, varscan2
- TCEAL7 | c.266A>C p.N89T | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV60125315; called by muse, mutect2, varscan2
- TDRD10 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV63812844; called by muse, mutect2, varscan2
- TENM1 | c.1774C>A p.P592T | Missense Mutation (SNP) | VAF 92/446 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as COSV64435528; called by muse, mutect2, varscan2
- TENM3 | c.3674C>T p.T1225M | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.412); catalogued as rs763018039, COSV69301957; called by muse, mutect2, varscan2
- TENM4 | c.4414G>A p.A1472T | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs776255394, COSV53635374; called by muse, mutect2, varscan2
- TGFBR2 | c.1254+2T>G p.X418_splice | Splice Site (SNP) | VAF 46/110 reads (42%) | catalogued as COSV55452699; called by muse, mutect2, varscan2
- TJP1 | c.3626C>T p.S1209F | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.11); catalogued as COSV62039450, COSV62043277; called by muse, mutect2, varscan2
- TMEM97 | c.97G>C p.V33L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV56878937; called by muse, mutect2, varscan2
- TNFRSF13C | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as COSV52169774; called by muse, mutect2
- TNFSF13 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs1167021681, COSV53433003; called by muse, mutect2, varscan2
- TRAF7 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as rs942789564, COSV58214178; called by muse, mutect2, varscan2
- TRIM49 | c.395C>A p.A132D | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100315952; called by muse, mutect2
- TTN | c.91883A>G p.E30628G (on ENST00000591111; = p.E23204G on NM_003319.4) | Missense Mutation (SNP) | VAF 14/180 reads (8%) | PolyPhen probably damaging (0.997); catalogued as COSV60154084; called by muse, mutect2
- UBE4B | c.3711G>A p.M1237I (on ENST00000343090 / NM_001105562.3; = p.M1108I on NM_006048.5) | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV53528935, COSV53535073; called by muse, mutect2, varscan2
- UBR4 | c.9856C>T p.R3286* | Nonsense Mutation (SNP) | VAF 21/51 reads (41%) | catalogued as COSV64392518; called by muse, mutect2, varscan2
- UBR4 | c.3123G>A p.W1041* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as COSV64392526; called by muse, mutect2, varscan2
- UNC5D | c.467A>C p.Y156S | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV54806884; called by muse, mutect2, varscan2
- VPS13D | c.3845G>A p.C1282Y | Missense Mutation (SNP) | VAF 79/174 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.182); catalogued as COSV50650000; called by muse, mutect2, varscan2
- WDR45 | c.436+1G>A p.X146_splice (on ENST00000376372 / NM_001029896.2; = p.X147_splice on NM_007075.3) | Splice Site (SNP) | VAF 121/132 reads (92%) | catalogued as CS132357, COSV59876327; called by muse, mutect2, varscan2
- WDR76 | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 13/28 reads (46%) | catalogued as COSV51039491; called by muse, mutect2, varscan2
- YWHAZ | c.650T>G p.I217R | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV62054363; called by muse, mutect2, varscan2
- YY1 | c.806A>G p.D269G | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV51763154; called by muse, mutect2, varscan2
- ZBTB26 | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 41/81 reads (51%) | catalogued as COSV65403555; called by muse, mutect2, varscan2
- ZFYVE1 | c.1171C>T p.R391W | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765009506, COSV59611673; called by muse, mutect2
- ZMAT2 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs887341712, COSV51226829; called by muse, mutect2, varscan2
- ZMYM3 | c.2915G>T p.G972V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV100077625; called by muse, mutect2, varscan2
- ZNF292 | c.1922A>G p.Y641C | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.974); catalogued as rs1425960517, COSV60541614; called by muse, mutect2, varscan2
- ZNF700 | c.1834A>T p.R612W | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54313503; called by muse, mutect2, varscan2
- ZNF77 | c.574T>A p.C192S | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.075); catalogued as COSV58822182; called by muse, mutect2, varscan2
- ZSWIM8 | c.3493C>T p.R1165* (on ENST00000605216 / NM_001242487.2; = p.R1170* on NM_015037.3) | Nonsense Mutation (SNP) | VAF 23/70 reads (33%) | catalogued as rs1320083360, COSV55214834; called by muse, mutect2, varscan2
- CDC42BPB | c.2665del p.A889Pfs*23 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | called by mutect2, pindel, varscan2
- EEF1A1 | c.175_190del p.V59Kfs*24 | Frame Shift Del (DEL) | VAF 27/115 reads (23%) | called by mutect2, pindel, varscan2
- FCGBP | c.2528C>T p.A843V | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- FOXD4L6 | c.680C>A p.A227D | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.255); called by mutect2, varscan2
- H1-2 | c.323_333del p.N108Sfs*10 | Frame Shift Del (DEL) | VAF 32/90 reads (36%) | called by pindel, varscan2
- HECA | c.1229del p.Q410Rfs*11 | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | called by mutect2, pindel, varscan2
- IGHG2 | c.506A>G p.K169R | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ITPKB | c.678_687dup p.V230Lfs*50 | Frame Shift Ins (INS) | VAF 32/92 reads (35%) | called by mutect2, varscan2
- KIF21A | c.2774T>G p.L925R (on ENST00000361418 / NM_001378440.1; = p.L912R on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- KMT2C | c.13693del p.Q4565Rfs*61 | Frame Shift Del (DEL) | VAF 22/72 reads (31%) | called by mutect2, pindel, varscan2
- KMT2C | c.6035del p.P2012Lfs*20 | Frame Shift Del (DEL) | VAF 62/170 reads (36%) | called by mutect2, pindel, varscan2
- MACF1 | c.14116G>A p.A4706T (on ENST00000372915; = p.A2639T on NM_012090.5) | Missense Mutation (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- MAGT1 | c.721_742del p.G241Ifs*7 (on ENST00000618282 / NM_001367916.1; = p.G273Ifs*7 on NM_032121.5) | Frame Shift Del (DEL) | VAF 12/93 reads (13%) | called by mutect2, pindel
- PFN1 | c.50_82del p.C17_D27del | In Frame Del (DEL) | VAF 14/36 reads (39%) | called by mutect2, pindel
- PIK3R4 | c.2886_2890del p.K962Nfs*6 | Frame Shift Del (DEL) | VAF 31/103 reads (30%) | called by mutect2, pindel, varscan2
- RTF2 | c.207A>C p.K69N | Missense Mutation (SNP) | VAF 5/113 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- THBS1 | c.115del p.A39Pfs*11 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | called by mutect2, pindel, varscan2
- TTN | c.99836_99839del p.T33279Rfs*11 (on ENST00000591111; = p.T25855Rfs*11 on NM_003319.4) | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | called by mutect2, pindel, varscan2
- ABHD3 | c.189G>A p.E63= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV56677104; called by muse, mutect2, varscan2
- AHNAK2 | c.9453G>A p.P3151= | Silent (SNP) | VAF 143/396 reads (36%) | catalogued as rs202104959, COSV60907416; called by muse, varscan2
- ANK2 | c.1605C>T p.H535= | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as COSV52169971; called by muse, mutect2, varscan2
- ARHGAP36 | c.639T>C p.F213= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV52268494; called by muse, mutect2, varscan2
- ARHGEF5 | c.921G>A p.Q307= | Silent (SNP) | VAF 19/140 reads (14%) | catalogued as COSV99282673; called by muse, mutect2, varscan2
- ATF2 | c.816A>G p.S272= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV51370755; called by muse, mutect2, varscan2
- ATP10B | c.1848G>A p.T616= | Silent (SNP) | VAF 68/190 reads (36%) | catalogued as rs373661469; called by muse, varscan2
- ATP11A | c.471C>T p.D157= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs140428971; called by muse, mutect2, varscan2
- AWAT2 | c.897C>T p.I299= | Silent (SNP) | VAF 61/101 reads (60%) | catalogued as rs1410400116, COSV52143766, COSV99339792; called by muse, varscan2
- BICDL1 | c.1665G>A p.G555= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV57493860; called by muse, mutect2, varscan2
- BSND | c.69G>A p.T23= | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as rs368632305; ClinVar: likely benign; called by muse, mutect2, varscan2
- CAB39L | c.807C>T p.I269= | Silent (SNP) | VAF 56/129 reads (43%) | catalogued as COSV61715566; called by muse, mutect2, varscan2
- CAPN10 | c.450A>G p.L150= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV54377426; called by muse, mutect2, varscan2
- CCSER1 | c.1809G>A p.A603= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as rs369689377, COSV100394742; called by muse, mutect2, varscan2
- CDC42BPG | c.1479A>G p.R493= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV61347988; called by muse, mutect2, varscan2
- CUX2 | c.1101G>A p.T367= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs373896743; called by muse, mutect2, varscan2
- CYLC1 | c.1764C>T p.F588= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV61413259; called by muse, mutect2, varscan2
- DBN1 | c.552C>T p.A184= | Silent (SNP) | VAF 60/160 reads (38%) | catalogued as COSV52790521; called by muse, mutect2, varscan2
- DSPP | c.726C>T p.S242= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs376633615; called by muse, mutect2, varscan2
- EGF | c.2877C>T p.H959= | Silent (SNP) | VAF 37/86 reads (43%) | catalogued as COSV54480640; called by muse, mutect2, varscan2
- F8 | c.1332A>G p.K444= | Silent (SNP) | VAF 40/197 reads (20%) | catalogued as CD982641, CM053241, CM0911142, CX067269, COSV64275135; called by muse, mutect2, varscan2
- FAM155B | c.1371G>C p.G457= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV52936757; called by muse, mutect2, varscan2
- FAM47A | c.1860T>C p.A620= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as COSV60497522; called by muse, mutect2, varscan2
- FAT4 | c.14394C>T p.N4798= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as rs776292701, COSV58692851; called by muse, mutect2, varscan2
- FCGR2B | c.531G>A p.S177= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs544225590, COSV99374940; called by muse, mutect2, varscan2
- FRY | c.8682C>T p.S2894= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs764560797, COSV66511383; called by muse, mutect2, varscan2
- FZD10 | c.1074C>A p.A358= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV57474277; called by muse, mutect2, varscan2
- GAD2 | c.147C>T p.Y49= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs768975616, COSV52161230; called by muse, mutect2, varscan2
- IGHV2-70 | c.75G>A p.E25= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs181122105; called by muse, varscan2
- IGLV4-3 | c.222C>T p.S74= | Silent (SNP) | VAF 38/128 reads (30%) | catalogued as rs751718885; called by muse, mutect2, varscan2
- KIAA1217 | c.3987C>T p.S1329= | Silent (SNP) | VAF 45/95 reads (47%) | catalogued as rs747875827, COSV56818815; called by muse, mutect2, varscan2
- KMT2B | c.3282C>T p.D1094= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs1209805964, COSV55863714; called by muse, mutect2, varscan2
- KMT2C | c.4320A>G p.T1440= | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as rs1412920843, COSV51456677; called by muse, mutect2, varscan2
- LBR | c.1101T>C p.D367= | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as COSV55289796; called by muse, mutect2, varscan2
- LRP12 | c.2409A>G p.G803= | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as rs776750987, COSV52630424; called by muse, mutect2, varscan2
- LRRN2 | c.144C>T p.R48= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as rs781709899, COSV100912870, COSV65784154; called by muse, mutect2, varscan2
- MID2 | c.825T>G p.T275= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as COSV53311288; called by muse, mutect2, varscan2
- MRPL49 | c.72G>A p.R24= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as COSV53695918; called by muse, mutect2, varscan2
- MUC5B | c.15366G>A p.T5122= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as rs748622933, COSV71591152; called by muse, mutect2, varscan2
- NSG2 | c.27C>T p.S9= | Silent (SNP) | VAF 41/99 reads (41%) | catalogued as rs760047342, COSV57458466; called by muse, mutect2, varscan2
- NUP153 | c.2805T>G p.G935= | Silent (SNP) | VAF 29/70 reads (41%) | catalogued as COSV50446802, COSV50452530; called by muse, mutect2, varscan2
- PCDH11X | c.1086T>C p.N362= | Silent (SNP) | VAF 31/106 reads (29%) | catalogued as COSV100009813; called by muse, mutect2, varscan2
- PHKA1 | c.222C>A p.A74= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV59807578; called by muse, mutect2, varscan2
- PIGZ | c.1485G>A p.L495= | Silent (SNP) | VAF 32/69 reads (46%) | catalogued as COSV53014026; called by muse, mutect2, varscan2
- PIK3C2A | c.1878T>A p.T626= | Silent (SNP) | VAF 48/134 reads (36%) | catalogued as COSV56404324; called by muse, mutect2, varscan2
- PLAUR | c.240G>C p.R80= | Silent (SNP) | VAF 32/59 reads (54%) | catalogued as COSV55390370; called by muse, mutect2, varscan2
- PTEN | c.60A>G p.G20= | Silent (SNP) | VAF 35/100 reads (35%) | catalogued as COSV64299027, COSV64299079; called by muse, varscan2
- PTPN14 | c.516G>A p.L172= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as COSV65285271; called by muse, mutect2, varscan2
- PUS10 | c.825A>G p.V275= | Silent (SNP) | VAF 102/354 reads (29%) | catalogued as rs766852592, COSV57453263; called by muse, varscan2
- SAMD8 | c.729C>T p.R243= | Silent (SNP) | VAF 35/95 reads (37%) | catalogued as rs758478241, COSV65510201; called by muse, mutect2, varscan2
- SEMA3C | c.1323T>C p.D441= | Silent (SNP) | VAF 40/124 reads (32%) | catalogued as COSV54849463; called by muse, mutect2
- SIN3A | c.867G>A p.S289= | Silent (SNP) | VAF 64/156 reads (41%) | catalogued as rs769881227, COSV64583652; called by muse, mutect2, varscan2
- SMAD9 | c.825G>A p.S275= (on ENST00000379826 / NM_001127217.3; = p.S238= on NM_005905.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs374907507; called by mutect2, varscan2
- SNRNP200 | c.4821C>T p.S1607= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs1300558552, COSV60491305; called by muse, mutect2, varscan2
- SPTBN5 | c.633C>A p.G211= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100310950; called by muse, mutect2, varscan2
- SYT17 | c.1395C>T p.R465= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs375022285; called by muse, mutect2
- TMTC1 | c.1179G>A p.P393= (on ENST00000539277 / NM_001193451.2; = p.P285= on NM_175861.3) | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs372059579; called by muse, mutect2, varscan2
- TRPA1 | c.2316T>A p.T772= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV51565467, COSV51565910; called by muse, mutect2, varscan2
- TRPV4 | c.2494C>T p.L832= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs377399452, COSV55683134; called by muse, mutect2, varscan2
- ZCCHC13 | c.120C>T p.S40= | Silent (SNP) | VAF 33/59 reads (56%) | catalogued as rs759474922, COSV59866416; called by muse, mutect2, varscan2
- ZNF831 | c.903G>A p.L301= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as COSV64041848; called by muse, mutect2, varscan2
- CXCL12 | c.266+883G>A | Intron (SNP) | VAF 5/15 reads (33%) | catalogued as rs762131157, COSV100638895; called by muse, mutect2, varscan2
- MACF1 | c.15832-8659G>A | Intron (SNP) | VAF 14/28 reads (50%) | catalogued as COSV57128792; called by muse, varscan2
- PIGF | c.546+4367A>G | Intron (SNP) | VAF 8/16 reads (50%) | catalogued as COSV99475711; called by muse, varscan2
- SUSD4 | c.725-5571T>G | Intron (SNP) | VAF 22/66 reads (33%) | catalogued as COSV100663599; called by muse, varscan2
